Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PW, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PW-01A (Primary Tumor).

[page 1 of 3]
	W 8/3/11	

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

Papillary carcinoma right thyroid lobe T2N0M0.

Specimens Submitted:

- 1: Total thyroidectomy
- 2: Left inferior parathyroid tissue?

DIAGNOSIS:

1. Total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type
Three foci

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe
Isthmus

Tumor Size:

Right lobe: 4.6 cm carcinoma and 2.0 cm carcinoma; isthmus: 3.5 cm carcinoma

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Present

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Adenoma(s) (away from the carcinoma):

1CD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
W 8/3/11

[page 2 of 3]
Not Identified
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not Identified

2. Left inferior parathyroid tissue?:

Lymph Node Dissection:

Number of lymph nodes examined: 1

Number of lymph nodes with metastatic disease: 1

Psammoma body is identified, consistent with metastatic papillary thyroid carcinoma

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

M.D.

1. The specimen is received fresh and is labeled "total thyroidectomy short stitch - right superior pole, long stitch - left lower pole" and consists of a thyroid weighing 33.5 g. The right lobe measures 5.1 x 3.1 x 2.3 cm, the left lobe measures 4 x 2.8 x 1.1 cm and the isthmus measures 5.2 x 3 x 2.2 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals the right lobe is predominantly replaced by a pink-tan soft nodule measuring 4.6 x 2.9 x 2.6 cm (nodule 1). Immediately adjacent to the nodule is a second nodule (2 x 1.2 x 1 cm) with a thick capsule and filled with yellow-brown translucent fluid. The isthmus has a third nodule (3.5 x 2.8 x 2.3 cm) with a heterogeneous cut surface composed of pale pink tissue with granular tan tissue. The remaining thyroid parenchyma is red tan and beefy. Representative sections of nodule one and nodule three are submitted for TPS. The nodules are entirely submitted and the left lobe is representatively submitted.

Summary of sections:

N1 - nodule, right lobe

N1/2- nodule one and two

N2- nodule, right lower lobe

N3-nodule, isthmus

LL - left lobe

M.D.

2. The specimen is received fresh, "left inferior parathyroid tissue?" and consists of a fragment of pink-tan tissue (0.4 x 0.2 x 0.2 cm). The specimen is entirely submitted in one cassette.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
1	LL	1
4	N1	4
1	N1/2	1
2	N2	2
7	N3	7

[page 3 of 3]
Part 2: Left inferior parathyroid tissue?

Block	Sect. Site	PCs
1	U	1

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

Date Reported:

Addendum Diagnosis

PART 1: There is an additional papillary microcarcinoma (0.6 cm) with tall cell features in the isthmus.

*** Report Electronically Signed ***
Signed out by [REDACTED]

Source: NCI Genomic Data Commons file 6777d419-fb9e-4714-abf5-dc4b3289fd41 (TCGA-DJ-A2PW.AED8092A-40A2-4376-AB04-8D31896D7FE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).